Gene-level copy-number profile of specimen HCM-SANG-0299-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0299-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS.
Specimen HCM-SANG-0299-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d88c2a6e-07be-4e6a-94cb-89900cd47bc6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0299-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/90ef9e27-793a-42c5-b77d-34a555c2ddbf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 535; copy number 1: 651; copy number 2: 24,726; copy number 3: 21,050; copy number 4: 11,552; copy number 5: 214; copy number 6: 20; copy number 7: 8; copy number 10: 9; copy number 12: 65; copy number 17: 8; copy number 21: 2; copy number 22: 3; copy number 32: 3; copy number 99: 17; copy number 116: 7; copy number 117: 19; copy number 121: 12; copy number 124: 8; copy number 128: 2.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:245,673,732–245,676,478, 1 gene (within-gene range 0–4): AC104462.1.
- chr13:18,467,172–18,944,284, 22 genes: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388, FEM1AP4, LINC00387, TERF1P5, FAM207BP, GXYLT1P1, CNN2P12, ZNF965P, CYP4F34P, SNX18P26, LINC00328-2P, ANKRD20A9P, RHOT1P3, RNU6-55P, RNU6-76P, SNX19P2, LINC00408, AL355516.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 397 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,938,744–147,003,618, 3 genes, copy number 5: NBPF12, PFN1P8, AC244394.3.
- chr1:223,951,394–223,992,594, 2 genes, copy number 5 (within-gene range 3–5): GTF2IP20, RNU6-1319P.
- chr5:32,522,758–42,191,523, 148 genes, copy number 5 (broad region; genes not listed).
- chr8:86,553,977–86,743,675, 1 gene, copy number 5 (within-gene range 4–5): CNGB3.
- chr8:86,657,388–88,887,573, 17 genes, copy number 5 (within-gene range 4–5): GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1.
- chr8:90,058,608–90,687,863, 3 genes, copy number 5 (within-gene range 3–5): CALB1, AC004083.1, LINC00534.
- chr8:101,166,805–103,501,895, 68 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:125,648,327–129,683,770, 48 genes, copy number 116–128 (within-gene range 3–128): AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr12:22,609,228–28,978,685, 107 genes, copy number 10–99 (within-gene range 2–99) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 579. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
